Gene-level copy-number profile of tumor specimen TCGA-13-A5FU-01A from TCGA case TCGA-13-A5FU, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Retroperitoneum; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 60.9 years (22,256 days).
Specimen TCGA-13-A5FU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.5a750811-6d30-463b-8f85-fc062087be51.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-A5FU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 821 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/91b899d1-58f0-4904-8be6-6f4d4f6d4685

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,007; copy number 2: 14,060; copy number 3: 21,571; copy number 4: 14,595; copy number 5: 4,739; copy number 6: 1,614; copy number 7: 363; copy number 8: 1,024; copy number 9: 396; copy number 10: 60; copy number 11: 20; copy number 12: 2; copy number 13: 6; copy number 14: 74; copy number 15: 31; copy number 17: 9; copy number 20: 14; copy number 26: 201; copy number 27: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-A5FU-01A-11D-A402-01): tumor purity 0.67, ploidy 3.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,917 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–154,325,325, 490 genes, copy number 8 (broad region; genes not listed).
- chr6:60,719,222–62,611,327, 13 genes, copy number 7–13: GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1, DHFRP5, AL355375.1, AL355375.2.
- chr6:63,635,802–63,779,336, 1 gene, copy number 13 (within-gene range 3–13): PHF3.
- chr6:63,797,189–63,857,769, 3 genes, copy number 13: AL354719.1, SCAT8, GCNT1P4.
- chr8:41,032,892–43,674,591, 81 genes, copy number 9 (broad region; genes not listed).
- chr8:54,247,633–54,479,963, 8 genes, copy number 7: AC044836.1, RNU105C, AC027250.1, AC027250.2, RN7SL250P, SOX17, AC091076.1, TRMT112P7.
- chr8:54,522,799–54,523,297, 1 gene, copy number 7: SEC11B.
- chr8:76,162,119–77,537,290, 15 genes, copy number 8 (within-gene range 5–8): AC011029.1, RNU2-54P, AC067773.1, LINC01109, LINC01111, ZFHX4-AS1, AC013509.1, MRPL9P1, ZFHX4, AC011716.1, AC023200.1, MIR3149, PEX2, HIGD1AP18, AC062004.1.
- chr8:118,189,455–135,742,495, 260 genes, copy number 7–8 (broad region; genes not listed).
- chr8:135,977,329–135,980,588, 1 gene, copy number 8: AC103955.1.
- chr8:137,424,904–139,127,953, 11 genes, copy number 8–11: ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2.
- chr9:18,573,306–19,786,928, 24 genes, copy number 10: MIR3152, RN7SKP258, RAP1BP1, SAXO1, AL356000.1, RRAGA, HAUS6, SCARNA8, RNU6-264P, Y_RNA, PLIN2, AL161909.1, DENND4C, AL161909.2, AL391834.1, AL391834.2, RPS6, NDUFA5P3, AL391834.3, ACER2, AL158206.1, MAP1LC3BP1, SLC24A2, C11orf98P1.
- chr9:35,161,992–37,034,268, 69 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr12:37,575,587–39,619,803, 26 genes, copy number 10 (within-gene range 2–10): ZNF970P, AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3.
- chr12:44,244,394–44,503,596, 4 genes, copy number 7–12: AC025030.2, AC025030.1, AC025253.1, AC025253.2.
- chr12:45,164,186–46,004,685, 15 genes, copy number 11: AC009248.3, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1.
- chr12:49,900,311–49,932,764, 1 gene, copy number 9 (within-gene range 5–9): LINC02395.
- chr12:49,950,737–50,480,004, 22 genes, copy number 9: AQP2, AC025154.2, AC025154.1, AQP5, AQP6, RACGAP1, ASIC1, SMARCD1, GPD1, COX14, AC074032.1, CERS5, LIMA1, AC008147.2, AC008147.3, AC008147.1, MIR1293, RNU6-1093P, AC008147.4, FAM186A, AC090058.1, LARP4.
- chr12:54,058,254–73,208,317, 495 genes, copy number 8–9 (within-gene range 5–9) (broad region; genes not listed).
- chr13:96,573,659–99,088,625, 42 genes, copy number 8: AMMECR1LP1, HSP90AB6P, TULP3P1, AL353581.1, RN7SKP7, OXGR1, LINC00456, MBNL2, AL161430.1, RNA5SP37, AL442067.3, RAP2A, AL442067.1, AL442067.2, PSMA6P4, AL359502.1, AL359502.2, RPL7AP61, AL356580.1, IPO5, FTLP8, FARP1, RNF113B, RN7SKP8, MIR3170, AL445223.1, AL161896.1, FARP1-AS1, STK24, AL356423.1, STK24-AS1, NUS1P4, CYCSP35, CALM2P4, RN7SL60P, SLC15A1, DOCK9, DOCK9-AS1, AL161420.1, RPL7L1P12, RNU6-83P, DOCK9-DT.
- chr16:34,978,744–35,912,516, 80 genes, copy number 7 (broad region; genes not listed).
- chr19:12,965,159–15,022,990, 90 genes, copy number 14–27 (within-gene range 6–27) (broad region; genes not listed).
- chr19:22,243,254–29,841,818, 141 genes, copy number 9–15 (broad region; genes not listed).
- chr20:45,293,445–45,579,326, 24 genes, copy number 7: MATN4, RBPJL, SDC4, AL021578.1, SYS1, SYS1-DBNDD2, TP53TG5, NDUFB4P10, DBNDD2, PIGT, MIR6812, AL031663.3, WFDC2, AL031663.2, RPL5P2, SPINT3, WFDC6, EPPIN-WFDC6, AL031663.1, HSPD1P21, EPPIN, WFDC8, RNA5SP485, CCNB1IP1P2.

Autosomal genes at a single copy (total copy number 1): 1,007. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
